Gene-level copy-number profile of tumor specimen TCGA-BR-6801-01A from TCGA case TCGA-BR-6801, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 70.2 years (25,637 days).
Specimen TCGA-BR-6801-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.636392f9-f9bc-46e3-b42b-e047acee374c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-6801-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b64cdfd6-b4bd-482a-b446-2713a7fe980b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 6; copy number 2: 50,287; copy number 3: 6,245; copy number 4: 2,071; copy number 5: 1,189.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-6801-01A-11D-1881-01): tumor purity 0.68, ploidy 1.31, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:246,108,626–246,426,119, 5 genes: SMYD3-AS1, CHCHD4P5, RNU6-1283P, SMYD3-IT1, Y_RNA.
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr4:90,838,903–90,839,037, 1 gene: TMSB4XP8.
- chr5:119,037,772–119,249,138, 5 genes (within-gene range 0–2): DMXL1, AC118465.1, LAMTOR3P2, RNU6-701P, MIR5706.
- chr6:101,452,917–101,454,245, 1 gene: AP002528.1.
- chr6:163,115,691–163,346,744, 4 genes: AL137182.1, PACRG-AS3, PACRG-AS1, AL031121.2.
- chr9:4,070,906–4,071,884, 1 gene: AL359095.1.
- chr20:14,884,250–14,935,363, 2 genes: MACROD2-AS1, AL138808.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,189 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:26,132,115–114,337,626, 1,189 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
